Somatic mutation profile of tumor specimen HCM-CSHL-0177-C25-01B (aliquot HCM-CSHL-0177-C25-01B-11D-A79L-36) from HCMI case HCM-CSHL-0177-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 64.1 years (23,399 days).
Specimen HCM-CSHL-0177-C25-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 835eefb4-a353-4073-a35d-01326f2684a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0177-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0177-C25-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/399fbaeb-9ddd-4b89-890b-2542fe7dd89f

The open-access MAF lists 54 somatic variants for this specimen: 43 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 10, Nonsense Mutation 6, Splice Region 1, Frame Shift Ins 1, Intron 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFTR | c.3472C>T p.R1158* | Nonsense Mutation (SNP) | VAF 19/129 reads (15%) | catalogued as rs79850223, CM920180, COSV50107726; ClinVar: pathogenic; called by muse, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 37/292 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.782+1G>T p.X261_splice | Splice Site (SNP) | VAF 61/254 reads (24%) | hotspot (GDC flag); catalogued as rs1555525429, COSV52665287, COSV52673806, COSV52698978; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS10 | c.2131G>A p.V711I | Missense Mutation (SNP) | VAF 58/437 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as rs564996469, COSV54355869; called by muse, varscan2
- ADORA2B | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 34/252 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as rs371657178; called by muse, mutect2, varscan2
- AL031777.2 | c.301G>A p.V101I | Missense Mutation (SNP) | VAF 44/332 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.975); catalogued as rs1561981692; called by muse, mutect2, varscan2
- ATM | c.6680G>A p.R2227H | Missense Mutation (SNP) | VAF 30/312 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs879254132, COSV53768386; ClinVar: uncertain significance; called by muse, mutect2
- CACNA1E | c.3285A>T p.E1095D | Missense Mutation (SNP) | VAF 36/232 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.186); catalogued as COSV62386722; called by muse, varscan2
- CCS | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 78/469 reads (17%) | catalogued as rs767806191; called by muse, mutect2
- CDK19 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100099120; called by muse, mutect2, varscan2
- ENTHD1 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751422820, COSV57317472; called by muse, mutect2, varscan2
- MUC5B | c.12806C>A p.P4269Q | Missense Mutation (SNP) | VAF 310/793 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.152); catalogued as COSV71592420; called by muse, mutect2, varscan2
- OR2M5 | c.691G>T p.G231* | Nonsense Mutation (SNP) | VAF 56/369 reads (15%) | catalogued as COSV63546261; called by muse, mutect2, varscan2
- PCDH8 | c.1054C>A p.P352T | Missense Mutation (SNP) | VAF 79/748 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58814412; called by muse, mutect2, varscan2
- PIANP | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 50/341 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs548735087, COSV57707946; called by muse, mutect2, varscan2
- RASGRP1 | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.545); catalogued as COSV60363832; called by muse, varscan2
- RIPOR3 | c.633G>C p.L211F | Missense Mutation (SNP) | VAF 119/428 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs920342685; called by muse, mutect2, varscan2
- SIM1 | c.1642C>T p.R548* | Nonsense Mutation (SNP) | VAF 39/316 reads (12%) | catalogued as COSV53492971; called by muse, mutect2, varscan2
- TG | c.5188C>T p.R1730C | Missense Mutation (SNP) | VAF 62/338 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs200793895, COSV55070371; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZFHX4 | c.1874C>T p.S625L | Missense Mutation (SNP) | VAF 64/371 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs748728059, COSV50745160; called by muse, mutect2, varscan2
- ABRAXAS2 | c.1094C>G p.A365G | Missense Mutation (SNP) | VAF 38/327 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- AL592490.1 | c.825G>A p.M275I | Missense Mutation (SNP) | VAF 67/437 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CCDC63 | c.1124A>G p.N375S | Missense Mutation (SNP) | VAF 57/271 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP83 | c.1672G>C p.E558Q | Missense Mutation (SNP) | VAF 39/273 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- DNAJC8 | c.443C>T p.T148I | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DOCK4 | c.17A>T p.E6V | Missense Mutation (SNP) | VAF 79/504 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DOK5 | c.583A>T p.T195S | Missense Mutation (SNP) | VAF 30/348 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.839); called by muse, mutect2
- EPHA7 | c.954G>T p.R318S | Missense Mutation (SNP) | VAF 41/281 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.419); called by mutect2, varscan2
- FAF1 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 26/207 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- FHL1 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 53/550 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0.006); called by muse, mutect2
- GABRE | c.949G>C p.V317L | Missense Mutation (SNP) | VAF 48/437 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- HAUS7 | c.261G>A p.W87* | Nonsense Mutation (SNP) | VAF 57/473 reads (12%) | called by muse, mutect2, varscan2
- INAVA | c.559C>G p.L187V | Missense Mutation (SNP) | VAF 76/463 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- KMT2C | c.12276G>A p.E4092= | Splice Region (SNP) | VAF 26/172 reads (15%) | called by muse, varscan2
- KRTAP3-1 | c.211T>C p.C71R | Missense Mutation (SNP) | VAF 89/577 reads (15%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEL2 | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 101/653 reads (15%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- MORC4 | c.1072G>A p.G358S | Missense Mutation (SNP) | VAF 32/279 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUP85 | c.1834C>A p.P612T | Missense Mutation (SNP) | VAF 36/321 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR10Z1 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 59/460 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSTK | c.704C>G p.A235G | Missense Mutation (SNP) | VAF 27/197 reads (14%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- RTL9 | c.2364_2389del p.S789Nfs*72 | Frame Shift Del (DEL) | VAF 74/556 reads (13%) | called by mutect2, pindel
- SPI1 | c.565dup p.I189Nfs*99 | Frame Shift Ins (INS) | VAF 231/703 reads (33%) | called by mutect2, pindel, varscan2
- USP24 | c.2494G>T p.E832* | Nonsense Mutation (SNP) | VAF 28/166 reads (17%) | called by muse, mutect2, varscan2
- B4GALNT4 | c.1716C>A p.P572= | Silent (SNP) | VAF 130/883 reads (15%) | called by muse, varscan2
- DERL1 | c.531T>C p.N177= | Silent (SNP) | VAF 58/249 reads (23%) | catalogued as rs1166366513; called by muse, mutect2, varscan2
- FAM135B | c.633C>A p.V211= | Silent (SNP) | VAF 77/366 reads (21%) | called by muse, mutect2, varscan2
- HOXB3 | c.513T>C p.G171= | Silent (SNP) | VAF 92/731 reads (13%) | catalogued as rs755210658, COSV61144937; called by muse, mutect2, varscan2
- KIF19 | c.343C>T p.L115= | Silent (SNP) | VAF 34/267 reads (13%) | called by muse, mutect2, varscan2
- OR1A1 | c.114A>T p.T38= | Silent (SNP) | VAF 71/348 reads (20%) | catalogued as COSV100410835; called by muse, mutect2, varscan2
- PTCHD3 | c.699C>T p.D233= | Silent (SNP) | VAF 73/461 reads (16%) | catalogued as rs1260956905, COSV71257235; called by muse, mutect2, varscan2
- SEMA5A | c.2220G>A p.P740= | Silent (SNP) | VAF 45/335 reads (13%) | catalogued as rs200621236, COSV66791508; called by muse, mutect2, varscan2
- THAP4 | c.507A>G p.Q169= | Silent (SNP) | VAF 78/472 reads (17%) | catalogued as rs763282526; called by muse, mutect2, varscan2
- TLE2 | c.2019C>T p.C673= | Silent (SNP) | VAF 58/353 reads (16%) | catalogued as rs1435181899; called by muse, mutect2, varscan2
- FMN1 | c.2044-2188G>A | Intron (SNP) | VAF 43/397 reads (11%) | catalogued as rs1384631998, COSV100569072; called by muse, mutect2, varscan2
